Somatic mutation profile of tumor specimen 3f52e236-1daa-4aa0-9a77-e3d043 (aliquot 3f52e236-1daa-4aa0-9a77-e3d043_D6_1) from CPTAC case 20BR006, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.4 years (23,877 days).
Specimen 3f52e236-1daa-4aa0-9a77-e3d043: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f39868d-c63d-44cd-a83b-40cf17f6e67a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ac6a7d2b-c376-49ca-8fc6-4b1e94 (Blood Derived Normal), aliquot ac6a7d2b-c376-49ca-8fc6-4b1e94_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e04c743f-bb86-488e-9dcc-a6e441a2507f

The open-access MAF lists 111 somatic variants for this specimen: 82 protein-altering or splice-affecting, 14 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 14, Frame Shift Del 7, Intron 5, Nonsense Mutation 5, 5'UTR 4, 3'UTR 4, Frame Shift Ins 2, In Frame Ins 2, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 82/179 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.531T>A p.Y177* | Nonsense Mutation (SNP) | VAF 126/179 reads (70%) | hotspot (GDC flag); catalogued as COSV100909304, COSV64289866, COSV64296956; called by mutect2, varscan2
- FASN | c.6128G>A p.R2043H | Missense Mutation (SNP) | VAF 241/517 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1215220329; called by muse, mutect2, varscan2
- FEM1C | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.174); catalogued as COSV57231360; called by muse, mutect2, varscan2
- FHOD3 | c.4001G>T p.R1334L (on ENST00000359247 / NM_001281739.3; = p.R1351L on NM_025135.5) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV57166173; called by muse, mutect2, varscan2
- GSX1 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs1201793231; called by muse, mutect2
- INSR | c.2704C>T p.R902C | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs1423107716, COSV57168323; called by muse, mutect2, varscan2
- IQGAP3 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772330297, COSV63254272; called by muse, mutect2, varscan2
- KIAA1109 | c.13942G>T p.D4648Y | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as COSV52660925, COSV52697357; called by muse, mutect2, varscan2
- LMO7 | c.4621C>T p.R1541C (on ENST00000357063; = p.R1222C on NM_005358.5) | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs146636938; called by muse, mutect2, varscan2
- LPA | c.3585G>A p.M1195I | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.782); catalogued as COSV100307948; called by muse, mutect2
- MAML2 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as rs929710318, COSV73263176; called by muse, mutect2, varscan2
- MEGF8 | c.7541G>A p.R2514H (on ENST00000251268 / NM_001271938.2; = p.R2447H on NM_001410.3) | Missense Mutation (SNP) | VAF 65/333 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as rs369692848, COSV52088151; called by muse, mutect2, varscan2
- MUC16 | c.39724C>A p.R13242S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.864); catalogued as rs749823098, COSV66695315; called by muse, mutect2, varscan2
- PLXNA2 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 127/443 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs772699228, COSV65437421; called by muse, mutect2, varscan2
- PM20D1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs572366251, COSV65649294; called by muse, mutect2, varscan2
- RPTN | c.1974C>A p.H658Q | Missense Mutation (SNP) | VAF 96/723 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV60169577; called by muse, mutect2, varscan2
- SERPINA4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 199/379 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs1278033042, COSV54069426; called by muse, mutect2, varscan2
- SPTA1 | c.3703C>A p.L1235M | Missense Mutation (SNP) | VAF 177/622 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935077; called by mutect2, varscan2
- TBC1D1 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs770966885; called by muse, mutect2, varscan2
- TEP1 | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs779605418, COSV52987617; called by muse, mutect2, varscan2
- THSD7B | c.2111T>A p.F704Y | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs1161816445; called by muse, mutect2, varscan2
- TP53 | c.723del p.C242Afs*5 | Frame Shift Del (DEL) | VAF 148/226 reads (65%) | catalogued as COSV53025058, COSV53153033, COSV53211006; called by mutect2, varscan2
- TRIM68 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs374562005; called by muse, mutect2, varscan2
- ZNF606 | c.2000T>C p.L667P | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145490639; called by muse, mutect2, varscan2
- ABCC4 | c.2006T>A p.L669* | Nonsense Mutation (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- ANO5 | c.2674_2699del p.S892Dfs*2 | Frame Shift Del (DEL) | VAF 57/246 reads (23%) | called by mutect2, pindel, varscan2
- BMX | c.2018A>T p.D673V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- CCSER2 | c.1604T>G p.M535R | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- CD151 | c.515C>G p.S172* | Nonsense Mutation (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- CFHR4 | c.1682_1688dup p.Q563Hfs*7 (on ENST00000367416 / NM_001201551.2; = p.Q317Hfs*7 on NM_006684.5) | Frame Shift Ins (INS) | VAF 25/198 reads (13%) | called by mutect2, varscan2
- CHML | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLIP1 | c.2329G>T p.D777Y (on ENST00000620786 / NM_001247997.1; = p.D766Y on NM_002956.2) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CPO | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 122/326 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CYB561A3 | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- DEF6 | c.1543G>C p.V515L | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DST | c.3542C>G p.T1181S (on ENST00000361203 / NM_001374722.1; = p.T855S on NM_001723.6) | Missense Mutation (SNP) | VAF 61/391 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EFCAB5 | c.3380C>G p.P1127R | Missense Mutation (SNP) | VAF 125/213 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ERP44 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- EXTL3 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 114/502 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FAM160A1 | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- GKN2 | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLYR1 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRHL1 | c.1643T>A p.L548H | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.9266T>C p.V3089A | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- KBTBD3 | c.1823C>A p.S608Y | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- KIAA0825 | c.3542G>T p.S1181I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2
- LGR5 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 135/382 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAEA | c.889A>C p.I297L (on ENST00000303400 / NM_001017405.3; = p.I256L on NM_005882.5) | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MROH7 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- MTR | c.1908_1921del p.W636* | Frame Shift Del (DEL) | VAF 192/730 reads (26%) | called by mutect2, varscan2
- NCOR1 | c.886del p.R296Efs*30 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | called by mutect2, pindel, varscan2
- PDCD2 | c.442A>G p.R148G | Missense Mutation (SNP) | VAF 77/138 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PRRC2C | c.830_833del p.N277Kfs*27 (on ENST00000367742; = p.N275Kfs*27 on NM_015172.4) | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by pindel, varscan2
- PRRC2C | c.7228C>T p.P2410S (on ENST00000367742; = p.P2408S on NM_015172.4) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PXN | c.1453G>T p.E485* (on ENST00000228307 / NM_001080855.3; = p.E451* on NM_002859.4) | Nonsense Mutation (SNP) | VAF 68/256 reads (27%) | called by muse, mutect2, varscan2
- RBM43 | c.865T>G p.L289V | Missense Mutation (SNP) | VAF 101/193 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RCN3 | c.129_143del p.P44_A48del | In Frame Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- RIN2 | c.1269_1270insCTA p.A423_K424insL (on ENST00000255006 / NM_001242581.1; = p.A374_K375insL on NM_018993.4 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 56/125 reads (45%) | called by mutect2, varscan2
- RIOX2 | c.1268A>T p.H423L (on ENST00000333396 / NM_001042533.2; = p.H422L on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR1 | c.11863T>A p.S3955T | Missense Mutation (SNP) | VAF 118/681 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.012); called by mutect2, varscan2
- RYR2 | c.7504T>A p.L2502I | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SALL2 | c.1419G>C p.E473D | Missense Mutation (SNP) | VAF 36/348 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SLC9C2 | c.127+1G>T p.X43_splice | Splice Site (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- SMC1B | c.1880A>G p.H627R | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEN | c.4619_4628del p.S1540Cfs*4 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- TAS2R13 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TDRD12 | c.997dup p.R333Kfs*8 | Frame Shift Ins (INS) | VAF 34/129 reads (26%) | called by mutect2, pindel, varscan2
- TENM4 | c.7801G>A p.A2601T | Missense Mutation (SNP) | VAF 122/504 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM63B | c.1931T>G p.I644S | Missense Mutation (SNP) | VAF 271/417 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRMT44 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSACC | c.128C>G p.T43S | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.017); called by muse, mutect2
- TSHZ1 | c.2689C>T p.L897F (on ENST00000580243 / NM_001308210.2; = p.L852F on NM_005786.6) | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC39A | c.1785A>T p.Q595H (on ENST00000447632 / NM_001297665.1; = p.Q560H on NM_001080494.3) | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- TUBA3C | c.1276del p.A426Qfs*54 | Frame Shift Del (DEL) | VAF 40/139 reads (29%) | called by mutect2, pindel, varscan2
- UMODL1 | c.2476G>T p.V826L (on ENST00000408910 / NM_001004416.2; = p.V954L on NM_173568.3) | Missense Mutation (SNP) | VAF 100/163 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- UROC1 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- VPS54 | c.488C>G p.P163R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR13 | c.170_171delinsAGTAC p.L57delinsQY | In Frame Ins (INS) | VAF 50/315 reads (16%) | called by pindel, varscan2*
- WDR18 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZHX3 | c.2599A>G p.N867D | Missense Mutation (SNP) | VAF 143/384 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF726 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDN3 | c.597C>G p.V199= (on ENST00000337938 / NM_001302455.2; = p.S211* on NM_207032.3) | Silent (SNP) | VAF 87/495 reads (18%) | called by muse, mutect2, varscan2
- EPX | c.1870T>C p.L624= | Silent (SNP) | VAF 96/362 reads (27%) | called by muse, mutect2, varscan2
- H3-2 | c.129G>T p.R43= | Silent (SNP) | VAF 86/597 reads (14%) | catalogued as rs782203529; called by muse, mutect2, varscan2
- MXRA5 | c.3339G>A p.A1113= | Silent (SNP) | VAF 99/282 reads (35%) | catalogued as rs754896583, COSV54243224, COSV54245643; called by muse, mutect2, varscan2
- NDUFV1 | c.105G>A p.L35= | Silent (SNP) | VAF 115/444 reads (26%) | called by muse, mutect2, varscan2
- OR56A4 | c.576T>C p.T192= | Silent (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1449C>T p.D483= | Silent (SNP) | VAF 51/652 reads (8%) | catalogued as COSV100971195; called by muse, mutect2
- PLEKHG6 | c.1743G>T p.V581= | Silent (SNP) | VAF 69/181 reads (38%) | called by muse, mutect2, varscan2
- SCN5A | c.4614C>A p.I1538= (on ENST00000333535 / NM_198056.3; = p.I1537= on NM_000335.5) | Silent (SNP) | VAF 38/171 reads (22%) | catalogued as COSV100351118; called by mutect2, varscan2
- SOX2 | c.87G>A p.A29= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- TBL1X | c.354C>T p.N118= | Silent (SNP) | VAF 53/198 reads (27%) | catalogued as rs780157551, COSV54280909; called by muse, mutect2, varscan2
- TKFC | c.1143G>A p.V381= | Silent (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- UNC13A | c.1224C>T p.P408= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs369156469; called by muse, mutect2, varscan2
- ZNF780B | c.126G>T p.L42= | Silent (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.-102G>C | 5'UTR (SNP) | VAF 63/199 reads (32%) | called by muse, mutect2, varscan2
- ASH1L | c.-265C>T | 5'UTR (SNP) | VAF 53/295 reads (18%) | catalogued as rs1185927851; called by muse, mutect2, varscan2
- CHRND | c.*556G>A | 3'UTR (SNP) | VAF 135/539 reads (25%) | called by muse, mutect2, varscan2
- LHCGR | c.536+1756G>T | Intron (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- MYBPC2 | c.-37C>T | 5'UTR (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- POLR3G | c.*98T>C | 3'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- RNFT2 | c.*2429G>C | 3'UTR (SNP) | VAF 54/102 reads (53%) | called by muse, varscan2
- SAMD3 | c.654+864C>T | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, varscan2
- SLC35C2 | c.-237C>T | 5'UTR (SNP) | VAF 90/497 reads (18%) | catalogued as rs750057545, COSV54755945; called by muse, varscan2
- SRRM2 | c.7734-219G>C | Intron (SNP) | VAF 133/417 reads (32%) | called by muse, mutect2, varscan2
- SSR2 | c.-1+10G>C | Intron (SNP) | VAF 43/224 reads (19%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.913G>C | RNA (SNP) | VAF 38/172 reads (22%) | called by muse, mutect2, varscan2
- STAT3 | c.2145-38C>G | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- UQCRB | c.*4188T>C | 3'UTR (SNP) | VAF 31/259 reads (12%) | called by muse, mutect2, varscan2
- WDR48 | chr3:39052008 G>A | 5'Flank (SNP) | VAF 27/87 reads (31%) | catalogued as rs777177658; called by muse, mutect2, varscan2
